Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4334, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4334-01A (Primary Tumor).

[page 1 of 3]
Clinical Diagnosis & History:

Renal mass, incidentally found.

Specimens Submitted:

- 1: SP: Rt. kidney, portion of adrenal gland and hilar lymph node
2: SP: Portion of rt. 11th rib
3: SP: Fat over tumor and colon

DIAGNOSIS:

- 1) KIDNEY AND ADRENAL GLAND; NEPHRECTOMY AND ADRENALECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE (CONVENTIONAL TYPE), NUCLEAR GRADE III/IV WITH FOCAL GRADE IV AREAS. THE PATTERN OF GROWTH IS SOLID. FOCAL METAPLASTIC OSSIFICATION IS ALSO SEEN. THE TUMOR GREATEST DIAMETER IS 11.6 CM. THE TUMOR EXTENDS THROUGH THE RENAL CAPSULE BUT IS CONFINED WITHIN GEROTA'S FASCIA. NO INVASION OF THE RENAL VEIN IS IDENTIFIED. HOWEVER, INTRATUMORAL VASCULAR INVASION IS PRESENT. ALL SURGICAL MARGINS ARE FREE OF TUMOR. THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE. THE ADRENAL GLAND IS UNREMARKABLE. THE LYMPH NODE STATUS IS AS FOLLOWS (EXPRESSED AS THE NUMBER OF METASTATIC NODES IN RELATION TO THE TOTAL NUMBER OF NODES EXAMINED): RENAL HILAR: 0/1.
- 2) RIB, PORTION OF RIGHT 11TH; EXCISION:
- GROSSLY UNREMARKABLE. SECTIONS NOT YET READY BECAUSE OF NEED TO DECALCIFY. IF SIGNIFICANT MICROSCOPIC ABNORMALITIES ARE FOUND, AN ADDENDUM REPORT WILL BE ISSUED.
- 3) "FAT OVER TUMOR AND COLON"; BIOPSY:
- FIBROADIPOSE TISSUE, NEGATIVE FOR TUMOR.

Special Studies:

Result	Special Stain	Comment
	CK7	
	Ki67	
	NEG CONT	
	IMM RECUT	

[page 2 of 3]
SURGICAL PATHOLOGY REPORT

1) The specimen is received fresh, labeled "Right Kidney, Portion of Adrenal Gland and Hilar Lymph Nodes". It consists of a nephrectomy specimen with an overall dimension of 24.0 x 14.0 x 11.0 cm. The vascular and ureteral margins are identified and uninvolved by tumor. A portion of adrenal gland at the superior pole of the kidney, measuring 1.5 cm in greatest dimension is identified and is unremarkable. The lower pole of the kidney demonstrates a bulging mass. A longitudinal section through the specimen demonstrates a large, orange-yellow, soft to firm mass arising from the lower pole of the kidney, measuring 11.5 cm in greatest dimension. Areas of hemorrhage and focal necrosis are also identified. The periureteral junction superior to the mass appears to be somewhat dilated. The tumor penetrates through the renal capsule and is predominantly present in the perirenal fat. Sections through the tumor demonstrates that the tumor comes to less than 1 mm to the perirenal fat surgical margin. No definite lymph nodes are identified in the hilar fat. Representative sections of the specimen, including some hilar fat, are submitted.

Summary of Sections:

VM – venous margin
AM – arterial margin
UM – ureteral margin
AD – adrenal gland
M – margin to the tumor to perirenal fat
TK – tumor to kidney
TP – tumor to pelvis
TF – tumor to perirenal fat
T – tumor
K – normal kidney
H – hilar fat

2) The specimen is received fresh, labeled "Portion of rt. 11th rib". It consists of two pieces of rib measuring 12.0 x 1.5 x 0.8 cm. Representative sections of the specimen are submitted after decal.

Summary of Sections:

U - undesignated

3) The specimen is received in formalin, labeled "Fat over tumor and colon". It consists of a single piece of adipose tissue measuring 2.0 x 1.0 x 0.5 cm. Entirely submitted.

Summary of Sections:

F - fat

Summary of Sections:

Part 1: SP: Rt. kidney, portion of adrenal gland and hilar lymph node

Block	Sect. Site	PCs
1	AD	2
1	AM	1
4	H	4
1	K	1
3	M	3
8	T	8
2	TF	2
2	TK	2
2	TP	2
1	UM	1
1	VM	2

Part 2: SP: Portion of rt. 11th rib

Block	Sect. Site	PCs
1	U	2

Part 3: SP: Fat over tumor and colon

[page 3 of 3]
SURGICAL PATHOLOGY REPORT

Block	Sect. Site	PCs
1	F	2

Source: NCI Genomic Data Commons file d070b40d-8f4f-4f07-a20b-c9d56e2005dc (TCGA-BP-4334.B1A02D10-922F-4B26-AE1B-89FB0672E2F9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).